Gene-level copy-number profile of tumor specimen TCGA-JV-A5VF-01A from TCGA case TCGA-JV-A5VF, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 69.8 years (25,505 days).
Specimen TCGA-JV-A5VF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.2047428f-14d9-474f-9dbe-57145bf6309c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JV-A5VF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/33fa2bb2-f297-43f2-a2ac-ff067078ed19

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 2,030; copy number 2: 22,096; copy number 3: 16,616; copy number 4: 17,296; copy number 5: 1,688; copy number 6: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JV-A5VF-01A-11D-A29M-01): tumor purity 0.81, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,863,625–88,584,530, 7 genes (within-gene range 0–2): PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr11:120,511,746–120,988,906, 2 genes (within-gene range 0–1): GRIK4, ELOCP22.
- chr16:65,141,751–65,176,713, 1 gene (within-gene range 0–2): LINC02126.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,755 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–43,705,518, 1,404 genes, copy number 5 (broad region; genes not listed).
- chr1:43,685,123–43,708,138, 1 gene, copy number 5: KDM4A-AS1.
- chr1:43,709,392–43,743,741, 3 genes, copy number 5: ST3GAL3-AS1, U6, AL451062.1.
- chr5:98,392,070–121,365,314, 261 genes, copy number 5 (broad region; genes not listed).
- chr6:124,644,434–130,574,112, 67 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr21:15,730,025–15,880,069, 1 gene, copy number 5 (within-gene range 2–5): USP25.
- chr21:15,928,296–17,296,596, 18 genes, copy number 5: MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1.

Autosomal genes at a single copy (total copy number 1): 1,993. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
